Somatic mutation profile of tumor specimen TCGA-24-1470-01A (aliquot TCGA-24-1470-01A-01W-0553-09) from TCGA case TCGA-24-1470, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 54.8 years (20,007 days).
Specimen TCGA-24-1470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abfcca8e-99dd-4089-9efc-deb5ff8ea2a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1470-10A (Blood Derived Normal), aliquot TCGA-24-1470-10A-01W-0553-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e399660-b9d7-4e02-b143-f5fac0b7fbeb

The open-access MAF lists 87 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Frame Shift Del 5, Nonsense Mutation 3, Splice Region 1, RNA 1, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG7 | c.1358T>A p.V453D | Missense Mutation (SNP) | VAF 61/255 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV56299862; called by muse, mutect2, varscan2
- ARID2 | c.1397A>C p.K466T | Missense Mutation (SNP) | VAF 109/382 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV57611769; called by muse, mutect2, varscan2
- AZIN2 | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV53859793; called by muse, mutect2, varscan2
- B3GALT4 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV65852047; called by muse, mutect2, varscan2
- BCHE | c.1414T>C p.F472L | Missense Mutation (SNP) | VAF 331/364 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV52260603; called by muse, mutect2, varscan2
- BRINP3 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as rs1277555053, COSV66536214; called by muse, mutect2, varscan2
- C18orf54 | c.682C>G p.P228A | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55618960; called by muse, mutect2, varscan2
- CDH10 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 75/114 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV52592499; called by muse, mutect2, varscan2
- CFAP53 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV68352598; called by muse, mutect2, varscan2
- CLHC1 | c.823G>C p.G275R | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV68464796; called by muse, mutect2, varscan2
- CPT1B | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV56418361; called by mutect2, varscan2
- DHRSX | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as rs759456411, COSV58137639; called by muse, mutect2, varscan2
- DNAH5 | c.7846A>G p.S2616G | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV54244382; called by muse, mutect2, varscan2
- EPHA1 | c.2129T>C p.L710P | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51974521; called by muse, mutect2, varscan2
- FAM171B | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV59006925; called by muse, mutect2, varscan2
- FGF23 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1411080842, COSV52977457; called by muse, mutect2, varscan2
- GABBR1 | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.248); catalogued as COSV63544021; called by muse, mutect2, varscan2
- HEATR3 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as COSV53531025; called by muse, mutect2
- HEG1 | c.1590C>A p.I530= | Splice Region (SNP) | VAF 51/81 reads (63%) | catalogued as rs202024429, COSV60764528; called by muse, mutect2, varscan2
- HIVEP1 | c.2746G>A p.G916R | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as rs574039329, COSV65102572, COSV65104120; called by muse, mutect2, varscan2
- HIVEP3 | c.2573T>C p.I858T | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56021067; called by muse, mutect2, varscan2
- IGSF22 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV60037343; called by muse, mutect2, varscan2
- INPP1 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 127/275 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59417171; called by muse, mutect2, varscan2
- INTS3 | c.2406G>C p.W802C | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55165188; called by muse, mutect2, varscan2
- ITPKB | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775979938, COSV55267237; called by muse, varscan2
- KAT8 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV54898455; called by muse, mutect2, varscan2
- KIF3C | c.628A>C p.N210H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53101149; called by muse, mutect2, varscan2
- LPAR4 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70912945, COSV70913207, COSV70913547; called by muse, mutect2, varscan2
- MARCKSL1 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as rs1196804835, COSV61482277; called by muse, mutect2, varscan2
- MED29 | c.226G>C p.D76H (on ENST00000615911; = p.D55H on NM_017592.4) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55395692; called by muse, mutect2, varscan2
- MXRA5 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.348); catalogued as COSV54245592; called by muse, mutect2
- MYCBP2 | c.4923A>C p.R1641S (on ENST00000357337; = p.R1679S on NM_015057.5) | Missense Mutation (SNP) | VAF 191/228 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV62033521; called by muse, mutect2, varscan2
- NAPB | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV63326215; called by muse, mutect2, varscan2
- NLRP3 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as rs773673175, COSV60224096, COSV60229478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPVF | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV56061359; called by muse, mutect2, varscan2
- NUP210L | c.4148T>A p.V1383E | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV55154643; called by muse, mutect2, varscan2
- OR4C11 | c.779dup p.T261Dfs*53 | Frame Shift Ins (INS) | VAF 7/60 reads (12%) | catalogued as rs764963140; called by mutect2, varscan2
- OR6B1 | c.747del p.Y250Ifs*19 | Frame Shift Del (DEL) | VAF 62/359 reads (17%) | catalogued as COSV68770669; called by mutect2, pindel, varscan2
- OR8H2 | c.445T>G p.Y149D | Missense Mutation (SNP) | VAF 141/370 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57946850; called by muse, mutect2
- PCDHB10 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as rs782674464, COSV53382337; called by muse, mutect2, varscan2
- PCLO | c.11211A>T p.Q3737H | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.742); catalogued as COSV61657038; called by muse, mutect2, varscan2
- PCNT | c.8461C>T p.Q2821* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV64031777; called by muse, mutect2
- PENK | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV59242770; called by muse, mutect2, varscan2
- PRG4 | c.2150T>C p.L717P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1215240950, COSV100798288; called by muse, varscan2
- RALGAPA1 | c.5098G>A p.G1700R | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.152); catalogued as COSV51892765; called by muse, mutect2, varscan2
- SETD7 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV56801549, COSV56801723; called by mutect2, varscan2
- SETX | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV56389015, COSV56391912; called by muse, varscan2
- SLC30A1 | c.882T>G p.F294L | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as COSV65361439; called by muse, mutect2, varscan2
- SLX4 | c.4284G>T p.W1428C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53567202; called by muse, mutect2, varscan2
- SYT13 | c.756C>G p.H252Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV50075991; called by muse, mutect2, varscan2
- TAF1 | c.4502C>T p.A1501V (on ENST00000373790 / NM_138923.4; = p.A1522V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99336627; called by muse, varscan2
- TP53 | c.780del p.S261Vfs*84 | Frame Shift Del (DEL) | VAF 55/86 reads (64%) | catalogued as rs1427471466, COSV53068418; called by mutect2, pindel, varscan2
- TRANK1 | c.3869T>C p.M1290T | Missense Mutation (SNP) | VAF 140/616 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV57160539; called by muse, mutect2, varscan2
- TRIP11 | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 102/176 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV50947091; called by muse, mutect2, varscan2
- TUBG1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52222532, COSV52222551; called by muse, mutect2, varscan2
- UBQLN2 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV57739483, COSV57740320; called by muse, mutect2, varscan2
- USP7 | c.2801A>T p.K934I | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV61216727; called by muse, mutect2, varscan2
- ZNF91 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.177); catalogued as COSV56090275; called by muse, mutect2, varscan2
- ZNF98 | c.1421C>T p.S474F | Missense Mutation (SNP) | VAF 88/493 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV63338754; called by muse, mutect2, varscan2
- DLG5 | c.1351_1365del p.T451_L455del | In Frame Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- DSEL | c.595del p.D199Ifs*41 | Frame Shift Del (DEL) | VAF 21/39 reads (54%) | called by mutect2, pindel, varscan2
- GPR3 | c.76_109del p.P26Cfs*24 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, varscan2
- NF1 | c.5847_5865del p.M1949Ifs*2 (on ENST00000358273 / NM_001042492.3; = p.M1928Ifs*2 on NM_000267.3) | Frame Shift Del (DEL) | VAF 19/33 reads (58%) | called by mutect2, pindel, varscan2
- PSME2 | c.497+1G>T p.X166_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2, varscan2
- TMCC2 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- ZNF492 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ABCG1 | c.1320G>A p.L440= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as COSV59208871; called by muse, mutect2, varscan2
- ACADVL | c.774C>T p.I258= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV50038487; called by muse, mutect2, varscan2
- AKR1C1 | c.769C>T p.L257= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as rs1160909326, COSV66499676; called by muse, mutect2, varscan2
- AL592490.1 | c.1795C>A p.R599= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as COSV69427365; called by muse, mutect2, varscan2
- APOBEC3D | c.903C>T p.A301= | Silent (SNP) | VAF 71/109 reads (65%) | catalogued as rs751024970, COSV53328005, COSV53329503; called by muse, mutect2, varscan2
- ARHGEF28 | c.1626A>G p.L542= | Silent (SNP) | VAF 51/67 reads (76%) | catalogued as COSV55265939; called by muse, mutect2, varscan2
- BAK1 | c.114C>T p.Y38= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as rs372257626; called by muse, mutect2, varscan2
- C2orf78 | c.1788A>G p.V596= | Silent (SNP) | VAF 85/210 reads (40%) | catalogued as COSV68518811; called by muse, mutect2, varscan2
- CPED1 | c.1338G>C p.L446= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV60009871; called by muse, mutect2, varscan2
- FAT1 | c.516C>T p.S172= | Silent (SNP) | VAF 108/138 reads (78%) | catalogued as rs548372738, COSV71675470; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR22 | c.57G>A p.V19= | Silent (SNP) | VAF 75/154 reads (49%) | catalogued as COSV51760552; called by muse, mutect2, varscan2
- MTCL1 | c.3987G>A p.K1329= (on ENST00000306329 / NM_001378206.1; = p.K1010= on NM_015210.4) | Silent (SNP) | VAF 32/43 reads (74%) | catalogued as COSV60410036; called by muse, mutect2, varscan2
- NOS2 | c.117G>C p.V39= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- PCDH15 | c.1285C>T p.L429= | Silent (SNP) | VAF 82/231 reads (35%) | catalogued as COSV57369089; called by muse, mutect2
- RNASEH1 | c.489C>T p.Y163= | Silent (SNP) | VAF 151/239 reads (63%) | catalogued as COSV59439469; called by muse, mutect2, varscan2
- RNF182 | c.705T>C p.V235= | Silent (SNP) | VAF 172/591 reads (29%) | catalogued as COSV70369840; called by muse, mutect2, varscan2
- SEZ6L | c.2470C>T p.L824= | Silent (SNP) | VAF 41/85 reads (48%) | catalogued as COSV50676990; called by muse, mutect2, varscan2
- SMYD1 | c.186C>G p.L62= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as COSV70225747; called by muse, mutect2, varscan2
- UBASH3A | c.996G>A p.P332= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs138698980; called by muse, mutect2, varscan2
- ABCC9 | chr12:21801057 C>T | 3'Flank (SNP) | VAF 41/162 reads (25%) | catalogued as rs773377070, COSV53963021; called by muse, mutect2, varscan2
- FBXL21P | n.864G>A | RNA (SNP) | VAF 7/39 reads (18%) | catalogued as rs191830002, COSV99778188; called by muse, mutect2, varscan2
